Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAE9, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAE9-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Hepatocellular carcinoma suggested

Specimen : Liver and Liver mass

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Partial hepatectomy

Organs: Liver (19.0 x 12.5 x 4.3 cm, 374.0 gm)

Lesion: A well-defined round firm mass (5.0 x 4.8 x 4.0 cm)

Cut surface: Yellowish tan and granular appearance

Gross type:

HCC: Expanding nodular

Resection margin: Not involved grossly (safety margin: 1.0 cm)

Others:

Satellite nodule: No

Representative sections were submitted.

Gross photo: Present

Blocks

T1-4, TB, tumor mass x 5

NB, L, liver parenchyma x 2

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

Q1 5/20/14

MICROSCOPIC:

Hepatocellular carcinoma: Yes

The worst differentiation III

The major differentiation II

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: No

Fibrous capsule formation: Complete capsule

Capsular infiltration: No

Septum formation: No

Surgical resection margin invasion: No, safety margin (1.0 cm)

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: No

Intrahepatic metastasis: Unknown

Multicentric occurrence: Unknown

NOT reported. Gross:

liver,ectomy,hepatocellular carcinoma,Steatohepatitis,mild steatosis,periportal fibrosis

T56000, P10, M81703, Steatohepatitis, mild steatosis, periportal fibrosis

DIAGNOSIS:

Liver, partial hepatectomy:

Hepatocellular carcinoma, moderately differentiated

[page 2 of 2]
Steatohepatitis with mild steatosis and periportal fibrosis (stage 2)
Suggestion :

Source: NCI Genomic Data Commons file 24d3718d-d254-488e-8017-c840adb5d15e (TCGA-DD-AAE9.64700E97-F031-49DE-83F0-8CCDBDEE23AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).